Gene-level copy-number profile of tumor specimen ALCH-ABRV-TTP1-A from ALCHEMIST case ALCH-ABRV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.2 years (26,386 days).
Specimen ALCH-ABRV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddcba902-9561-4692-b800-783eb7443676.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABRV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/f3bd311b-517e-4ef6-ae74-92f2b0750557

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 107; copy number 2: 58,004; copy number 3: 255; copy number 4: 16; copy number 5: 6; copy number 6: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 6 (within-gene range 2–6): TTC34, AC242022.2, AC242022.1.
- chr9:40,883,634–40,883,763, 1 gene, copy number 5: AL353626.2.
- chr11:48,880,111–48,908,946, 4 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr16:35,021,749–35,085,060, 5 genes, copy number 5 (within-gene range 2–5): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.

Autosomal genes at a single copy (total copy number 1): 107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
